Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5K1, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5K1-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

BIRTHDATE:

PAGE #: 2
SEX: M
ADM DATE:

OPER DATE:

PROCEDURE: APMI

ADDITIONAL REPORT FOLLOWING ADDITIONAL SECTIONS AND IMMUNOHISTOCHEMISTRY:

Please see diagnosis below.

PROCEDURE: APDX

1. Adrenal gland, left, resection: Adrenocortical carcinoma, low-grade by mitotic activity, with capsular and vascular invasion. Ki-67 proliferation marker shows a proliferation rate above that typically found in benign tumors. See COMMENT.

COMMENT:

This adrenocortical neoplasm has a very low mitotic activity as assessed by counting of mitotic figures. The Ki-67 proliferation marker shows a proliferation rate that is consistent with the diagnosis of low grade adrenocortical carcinoma. In addition, research immunostains show a similar proliferation rate using topoisomerase 2-alpha. Furthermore, the tumor shows diffuse nuclear immunoreactivity for cyclin E which is also consistent with a diagnosis of carcinoma. (These research stains are not performed by a certified lab and therefore are not billed to the patient.

signing staff pathologist, have personally examined and interpreted the slides from this case.

"This test was developed and its performance characteristics determined by the Clinical Immunoperoxidase Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration. (The FDA has determined that such clearance is not necessary. This test is used for

ICD O-3
Carcinoma, adrenal cortex 8370/3
Site: Adrenal Gland Cortex C74.0
QID 11/30/13

Dual/Synch. Ancus Pathology Noted		

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:

PAGE #: 3

BIRTHDATE:

PAT TYP..

SEX: M

ADM DATE:

OPER DATE:

clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ["CLIA"] as qualified to perform high complexity testing)."

OPER DATE:

PROCEDURE: SPHS

year-old male with left adrenal mas.

PROCEDURE: SPGD

1. "Left adrenal" Received fresh in a medium container is a 110 gram adrenal with a scant amount of attached yellow adipose, 7.9 x 6.2 x 5.7 cm. The cut surface is remarkable for a 6.2 x 5.3 x 6.0 cm, tan-brown, faintly-nodular, soft, well-circumscribed tumor. The tumor has focal areas of bright-yellow necrosis occupying approximately 15% of the cut surface. Tumor abuts the margin. A 1.1 x 2.3 x 0.5 cm segments of normal adrenal gland is present. NO other abnormalities are noted. Photographs have been taken.

1A&B. Tumor to normal.

1C-G. Tumor to capsule.

1H. Normal adrenal.

PROCEDURE: SPDX

1. Adrenal gland, left, resection: Adrenocortical carcinoma, low-grade by mitotic activity, with capsular invasion. Additional report pending additional sections and immunohistochemistry.

, the signing staff pathologist, have personally examined and interpreted the slides from this case.

Source: NCI Genomic Data Commons file 74db6a08-95e3-43c0-9663-772a20628eeb (TCGA-OR-A5K1.54EFE89F-32E0-4E95-A841-728648D9D11E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).